Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A7SK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A7SK-01A (Primary Tumor).

[page 1 of 2]
A and C. Liver, left, lobectomy :

HEPATOCELLULAR CARCINOMA

Tumor number: one
Satellite nodule: no
Location :
Gross type: nodular with perinodular extension
Size(cm): 4x3.5x3
Differentiation: The worst differentiation: Edmondson grade IV
Differentiation: The major differentiation: Edmondson grade III
Histologic type : microtrabecular
Cell type : hepatic
Tumor necrosis : yes (10 %)
Hemorrhage : no
Fatty change : no
Fibrous capsule : partial
Infiltration of capsule : yes
Septum formation : yes
Surgical margin invasion : no(margin of the clearance : 0.3 cm)
Serosa invasion: no
Portal vein invasion : no
Bile duct invasion : no
Hepatic vein invasion : no
Hepatic artery invasion : no
Microvessel invasion : yes
Intrahepatic metastasis : no
Multicentric occurrence : no
T stage : pT1
N stage: No metastasis in all 1 lymph node(pN0)

Non-tumor liver

Chronic hepatitis : yes
Etiology : HCV
Grade, Icbular : minimal
Grade, portoperiportal : mild
Stage(fibrosis) : periportal
Cirrhosis : no
Dysplastic nodule : no

ICD-O-3
Carcinoma, hepatocellular NOS
Site Liver
C22.0
817013
JW 10/24/13

[page 2 of 2]
Ductal epithelial dysplasia : no
Other liver disease : no
Fatty change, macrovesicular (10%)

B. Gallbladder, cholecystectomy :

Chronic cholecystitis

<Result of special stain>

Iron(Block #A9) : Negative

<Results of immunohistochemical stain>

Cytokeratin 7(Block #A9) : Positive in bile duct

Cytokeratin 7, Cytokeratin 19, Hepatocyte(Block #A8) : Negative

- A. The specimen received in formalin is a product of lobectomy of liver, measuring 12x8x4cm and weighing 175gm. The external surface shows a protruding subcapsular mass. The parenchyma resection margin is clear. On section, there are nodular with perinodular extension type mass, measuring 4x3.5x3cm. The mass is 0.3cm apart from parenchymal resection margin. On serial section, the remaining parenchyma is unremarkable. Representative sections are embedded in 9 cassettes. (A1to4-one plane, A5to8-one plane, A9-background liver)
- B. The specimen received in formalin consists of a gallbladder, measuring 9cm in length and 1.5cm in diameter. The capsular surface is unremarkable. The wall measures 0.2cm in maximal thickness. The mucosa is greenish velvety. There is no stone or polyp. Representative sections are embedded in one cassette.
- C. The specimen received in formalin is a lump of adipose tissue labeled "lymph node". Entirely embedded in one cassette.

H&E(11), MT(1), RTC(1), D-PAS(1), Iron(1), Cytokeratin 7(1),
Cytokeratin 19(1), Hepatocyte(1)

Criteria	kw 8/12/13	Yes	No
HI/PA Discrepancy			

Source: NCI Genomic Data Commons file cd7e8eef-fc02-46bd-8cf5-33d2fd5b6953 (TCGA-RC-A7SK.5C08444C-DD26-44C1-BDF3-E6E581126F38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).